Somatic mutation profile of tumor specimen C3N-00835-04 (aliquot CPT0379760009) from CPTAC case C3N-00835, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oncocytoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 68.3 years (24,933 days).
Specimen C3N-00835-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 505bc1d9-bd7b-4b05-b8fb-0e9699ad0a67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00835-71 (Blood Derived Normal), aliquot CPT0386430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/caffe357-4057-4b52-b578-fd40e2c5af77

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Frame Shift Del 3, Silent 2, Splice Region 1, Nonsense Mutation 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1G | c.5002C>T p.R1668C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1369128414, COSV61730920; called by muse, mutect2
- CAMK2N2 | c.186C>A p.D62E | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.053); catalogued as rs1400529693; called by muse, mutect2, varscan2
- DGKI | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 10/112 reads (9%) | catalogued as rs1259961080, COSV55934682; called by muse, mutect2
- H3C8 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.102); catalogued as rs750087996; called by muse, mutect2, varscan2
- POLD4 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.22); catalogued as rs980903205; called by muse, mutect2, varscan2
- PWWP3B | c.514C>G p.P172A | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs772556021, COSV100531729; called by muse, mutect2, varscan2
- ZNF365 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.162); catalogued as rs572179220; called by muse, mutect2, varscan2
- ADAMTS9 | c.3714del p.C1239Vfs*14 | Frame Shift Del (DEL) | VAF 19/126 reads (15%) | called by mutect2, pindel, varscan2
- ASPM | c.7535A>T p.Q2512L | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.254); called by muse, mutect2
- CNDP1 | c.1352T>C p.I451T | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRCC1 | c.222_227delinsG p.C75Yfs*17 | Frame Shift Del (DEL) | VAF 65/343 reads (19%) | called by pindel, varscan2*
- LRFN5 | c.1887G>T p.L629F | Missense Mutation (SNP) | VAF 93/371 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MARK3 | c.790_793del p.R264Yfs*2 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, varscan2
- MDH1B | c.24T>A p.G8= | Splice Region (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- RCBTB1 | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- SYT6 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL6R | c.1281C>A p.L427= | Silent (SNP) | VAF 15/342 reads (4%) | called by muse, mutect2
- MSN | c.1674C>A p.T558= | Silent (SNP) | VAF 22/125 reads (18%) | called by muse, mutect2, varscan2
- PICK1 | c.-50T>G | 5'UTR (SNP) | VAF 31/123 reads (25%) | called by muse, mutect2, varscan2
- RUSF1 | c.*765T>C | 3'UTR (SNP) | VAF 49/191 reads (26%) | called by muse, mutect2, varscan2
